Somatic mutation profile of tumor specimen TCGA-BQ-5891-01A (aliquot TCGA-BQ-5891-01A-11D-1589-08) from TCGA case TCGA-BQ-5891, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.3 years (20,945 days).
Specimen TCGA-BQ-5891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ca09cdb-5828-4f80-90d2-1991ccc6e8e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5891-11A (Solid Tissue Normal), aliquot TCGA-BQ-5891-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32d441b3-a6be-4213-8ef6-dba1d426d76f

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 13, Silent 10, Splice Site 1, Frame Shift Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6A | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1398588309, COSV52022999; called by muse, mutect2, varscan2
- AKAP10 | c.593T>C p.F198S | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56731073; called by muse, mutect2, varscan2
- CCDC116 | c.743C>G p.S248* | Nonsense Mutation (SNP) | VAF 7/170 reads (4%) | catalogued as COSV53037761; called by muse, mutect2
- EFCAB13 | c.2393A>G p.N798S | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs137885108; called by muse, mutect2, varscan2
- IL10RA | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.639); catalogued as rs145975996; called by muse, mutect2, varscan2
- IRF5 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs1406341251, COSV50857599; called by muse, mutect2, varscan2
- LRP1B | c.3895C>G p.Q1299E | Missense Mutation (SNP) | VAF 78/92 reads (85%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as COSV67214728, COSV67218446; called by muse, mutect2, varscan2
- MUC16 | c.21728C>A p.S7243Y | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); catalogued as rs1235748913, COSV67459700, COSV67465196; called by muse, mutect2
- OR52J3 | c.533A>T p.H178L | Missense Mutation (SNP) | VAF 99/103 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66746403, COSV66746904; called by muse, mutect2, varscan2
- SORCS1 | c.2216A>G p.N739S | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as COSV53865681; called by muse, mutect2, varscan2
- USP45 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 73/80 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV57328792; called by muse, mutect2, varscan2
- XPO1 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs751737799, COSV68945947; called by muse, mutect2
- ZNF761 | c.948T>A p.H316Q | Missense Mutation (SNP) | VAF 86/101 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61888308; called by muse, mutect2
- ZNF761 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 87/102 reads (85%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV61888317; called by muse, mutect2
- ACADL | c.1199+2del p.X400_splice | Splice Site (DEL) | VAF 57/61 reads (93%) | called by mutect2, pindel*, varscan2
- KL | c.497_498insTGGCAGCGCGGGCCTCCCCAA p.N166_R167insGSAGLPN | In Frame Ins (INS) | VAF 15/16 reads (94%) | called by muse*, mutect2
- SETD2 | c.3276_3277del p.S1093Lfs*2 | Frame Shift Del (DEL) | VAF 109/164 reads (66%) | called by mutect2, pindel, varscan2
- DRD1 | c.57C>T p.D19= | Silent (SNP) | VAF 66/170 reads (39%) | catalogued as COSV67104557; called by muse, mutect2, varscan2
- FSIP2 | c.17367T>C p.D5789= | Silent (SNP) | VAF 59/61 reads (97%) | catalogued as COSV58085393; called by muse, mutect2, varscan2
- GGTLC1 | c.120G>A p.L40= | Silent (SNP) | VAF 53/93 reads (57%) | catalogued as COSV53847720; called by muse, mutect2, varscan2
- KLHL3 | c.1587C>T p.N529= | Silent (SNP) | VAF 82/226 reads (36%) | catalogued as rs562736621, CM122586, COSV59054290; called by muse, mutect2, varscan2
- MICU2 | c.639G>A p.V213= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV66673963; called by muse, mutect2
- PCDHGA1 | c.1677G>A p.A559= | Silent (SNP) | VAF 193/395 reads (49%) | catalogued as COSV65296420; called by muse, mutect2, varscan2
- RANBP10 | c.105G>A p.L35= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV58157689; called by muse, mutect2, varscan2
- TMPRSS15 | c.2080A>C p.R694= | Silent (SNP) | VAF 97/104 reads (93%) | catalogued as COSV53039667; called by muse, mutect2, varscan2
- TXNRD2 | c.1071T>A p.I357= | Silent (SNP) | VAF 72/83 reads (87%) | catalogued as COSV68692114; called by muse, mutect2, varscan2
- UBR2 | c.5109G>A p.E1703= | Silent (SNP) | VAF 333/371 reads (90%) | catalogued as rs759673920, COSV65750134; called by muse, mutect2, varscan2
